TARGET case TARGET-10-PANYHW — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/2237aadd-3055-418f-9d2c-f8cf88a70665

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Biospecimens (1 sample)
- Sample TARGET-10-PANYHW-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_II_Discovery_20230727.xlsx:
- Overall Survival Time in Days: 3793
- WBC at Diagnosis: 17.8
- CNS Status at Diagnosis: CNS 1
- MRD Day 29: 4.9
- MRD Day 29 Sensitivity: 0.01
- Bone Marrow Site of Relapse: Yes
- CNS Site of Relapse: No
- Testes Site of Relapse: No
- Other Site of Relapse: No
- BCR ABL1 Status: Negative
- BMA Blasts Day 8: 86
- BMA Blasts Day 15: 12
- BMA Blasts Day 29: 2
- BMA Blasts Day 43: 0
- Down Syndrome: No
- DNA Index: 1
- Cell of Origin: B-Precursor
- ALL Molecular Subtype: None of the above
